Somatic mutation profile of tumor specimen C3N-02923-04 (aliquot CPT0216660009) from CPTAC case C3N-02923, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 59.9 years (21,896 days).
Specimen C3N-02923-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8eb9f1d-89c1-40aa-bc4b-67ba2e83b9c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02923-71 (Blood Derived Normal), aliquot CPT0216750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe6d1bba-66f8-4f2a-b75a-73d3690380ca

The open-access MAF lists 350 somatic variants for this specimen: 245 protein-altering or splice-affecting, 59 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 223, Silent 59, Intron 19, Nonsense Mutation 15, RNA 13, 5'UTR 5, Splice Region 4, 5'Flank 3, Splice Site 3, 3'Flank 3, 3'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 50/314 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.503A>C p.H168P | Missense Mutation (SNP) | VAF 22/340 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52676197, COSV52682212, COSV52698349, COSV52762255; called by muse, mutect2
- ACACB | c.654-1G>T p.X218_splice | Splice Site (SNP) | VAF 49/385 reads (13%) | catalogued as COSV58142088; called by muse, mutect2, varscan2
- ADAMTS5 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV53178501; called by muse, mutect2
- ADGB | c.4390C>A p.Q1464K | Missense Mutation (SNP) | VAF 20/351 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV58848518; called by muse, mutect2
- ADGRL3 | c.1256G>T p.S419I (on ENST00000506720 / NM_001322402.2; = p.S351I on NM_015236.6) | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.405); catalogued as COSV101546829; called by muse, mutect2
- ALG1L | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 22/483 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as COSV61075435; called by muse, mutect2
- ANKFN1 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100593554; called by muse, mutect2
- ANKRD30B | c.922C>A p.R308S | Missense Mutation (SNP) | VAF 43/425 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs760939525, COSV100745737, COSV62814602; called by muse, mutect2
- ANO6 | c.1179G>T p.L393F | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1468109575; called by muse, mutect2
- ASCC3 | c.3418A>T p.R1140* | Nonsense Mutation (SNP) | VAF 16/330 reads (5%) | catalogued as rs1285917703; called by muse, mutect2
- ASTN2 | c.1775G>T p.G592V (on ENST00000313400 / NM_001365069.1; = p.G541V on NM_014010.5) | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100524696; called by muse, mutect2, varscan2
- ATR | c.7735G>A p.E2579K | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.305); catalogued as COSV63383268; called by muse, mutect2, varscan2
- BACH1 | c.2024G>T p.R675L | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV54519833, COSV54519879; called by muse, mutect2
- BRPF3 | c.3307G>T p.G1103C | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60207887; called by muse, mutect2
- C1QTNF5 | c.379C>G p.R127G | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV100264746; called by muse, mutect2
- CHORDC1 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1184752454; called by muse, mutect2
- CNTNAP2 | c.3115C>G p.Q1039E | Missense Mutation (SNP) | VAF 42/594 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372351365; ClinVar: uncertain significance; called by muse, mutect2
- COL22A1 | c.2246C>A p.T749K | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.031); catalogued as rs370563319; called by muse, mutect2, varscan2
- COL3A1 | c.3094-1G>T p.X1032_splice | Splice Site (SNP) | VAF 49/534 reads (9%) | catalogued as COSV100483326; called by muse, mutect2
- EPAS1 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs781173090; called by muse, mutect2
- FER1L6 | c.2184G>C p.R728S | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1290639728, COSV67552776; called by muse, mutect2
- FLG | c.1979C>A p.P660H | Missense Mutation (SNP) | VAF 62/780 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.732); catalogued as COSV64235619, COSV64244444; called by muse, mutect2
- FMNL3 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.349); catalogued as rs995767932; called by muse, mutect2, varscan2
- GALNT17 | c.1390G>C p.V464L | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV61153495, COSV61165790; called by muse, mutect2
- GJA8 | c.525C>A p.F175L | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1553242727; called by muse, mutect2, varscan2
- HCAR1 | c.129C>A p.H43Q | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as CM1212151; called by muse, mutect2, varscan2
- HSCB | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1569182882, COSV53262745; called by muse, mutect2
- ICMT | c.231C>G p.F77L | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV59474040; called by muse, mutect2
- IHH | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 44/546 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99838773; called by muse, mutect2
- IL17F | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 41/538 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs533677189, COSV60235218; called by muse, mutect2
- IMP4 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52091969; called by muse, mutect2
- KCNA2 | c.281C>A p.S94* | Nonsense Mutation (SNP) | VAF 28/357 reads (8%) | catalogued as COSV60369094; called by muse, mutect2
- KIAA1109 | c.2719A>T p.S907C | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs554671500; called by muse, mutect2
- KIAA2012 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.277); catalogued as rs1336130584, COSV55575611; called by muse, mutect2
- LDLR | c.259T>A p.W87R | Missense Mutation (SNP) | VAF 53/630 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM900152; called by muse, mutect2
- LHFPL3 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1223104844, COSV101308327; called by muse, mutect2
- LRP1B | c.12020C>T p.S4007F | Missense Mutation (SNP) | VAF 20/423 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV67273514; called by muse, mutect2
- LRP1B | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1420458852; called by muse, mutect2, varscan2
- LYRM7 | c.250G>T p.V84F | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.165); catalogued as rs1201547282, COSV65087092; called by muse, mutect2
- MDGA2 | c.2758T>G p.L920V (on ENST00000399232 / NM_001113498.2; = p.L622V on NM_182830.4) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100638894, COSV62105064; called by muse, mutect2, varscan2
- MUC17 | c.3057A>C p.E1019D | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV60294420; called by muse, mutect2
- MYH1 | c.1483C>T p.H495Y | Missense Mutation (SNP) | VAF 57/700 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs777299446; called by muse, mutect2
- MYO1D | c.2743C>T p.Q915* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | catalogued as COSV59007975; called by muse, mutect2
- NECTIN1 | c.1547A>T p.Y516F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99871764; called by muse, mutect2
- NKD2 | c.941C>G p.A314G | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as COSV99723891; called by muse, mutect2, varscan2
- NLGN1 | c.2443C>A p.P815T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.958); catalogued as COSV64335184; called by muse, mutect2, varscan2
- OAS2 | c.105C>G p.D35E | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.364); catalogued as COSV60802559; called by muse, mutect2
- OCM2 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 23/255 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs778218099, COSV57535604; called by muse, mutect2
- OR2L13 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100813798; called by muse, mutect2
- OR4C46 | c.511G>C p.V171L | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV60219992, COSV99080380; called by muse, mutect2
- OR51Q1 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 53/388 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV56178312; called by muse, mutect2, varscan2
- OR8K5 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57888540; called by muse, mutect2
- POM121L12 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 20/208 reads (10%) | catalogued as rs1418866673, COSV68694385; called by muse, mutect2
- PRPF8 | c.4792G>C p.D1598H | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59262317; called by muse, mutect2
- PYHIN1 | c.1123T>C p.F375L | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1304000747; called by muse, mutect2
- RXRA | c.1009G>T p.A337S | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1025445258; called by muse, mutect2
- SCN8A | c.3107A>T p.E1036V | Missense Mutation (SNP) | VAF 41/382 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.723); catalogued as COSV100633277, COSV61984182; called by muse, mutect2, varscan2
- SPARC | c.279C>G p.C93W | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50557943; called by muse, mutect2
- SPTA1 | c.5708T>C p.I1903T | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV100934955; called by muse, mutect2
- SPTA1 | c.3788A>G p.Q1263R | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs1428024877; called by muse, mutect2
- SPTLC2 | c.135C>A p.I45= | Splice Region (SNP) | VAF 14/214 reads (7%) | catalogued as COSV53643243; called by muse, mutect2
- TG | c.7341C>A p.S2447R | Missense Mutation (SNP) | VAF 64/734 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.609); catalogued as rs1444653329; called by muse, mutect2
- TIGIT | c.250C>G p.R84G | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV67328604; called by muse, mutect2, varscan2
- TNRC18 | c.7661C>T p.A2554V | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as rs1292135228; called by muse, mutect2
- TSHR | c.1809G>C p.K603N | Missense Mutation (SNP) | VAF 17/441 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV99992456; called by muse, mutect2
- TTLL5 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 15/251 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1337606986; called by muse, mutect2
- UBR5 | c.6713G>C p.R2238T | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV55293006; called by muse, mutect2
- UNC5C | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs1471595875; called by muse, mutect2
- UNC79 | c.6706G>T p.A2236S (on ENST00000393151 / NM_001346218.2; = p.A2059S on NM_020818.5) | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1444049195, COSV56400620; called by muse, mutect2, varscan2
- XDH | c.3593G>T p.G1198V | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65151194; called by muse, mutect2
- ZNF470 | c.171G>T p.R57S | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV100401239; called by muse, mutect2, varscan2
- ZNF479 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV100482996; called by muse, mutect2
- ZNF804A | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100167365; called by muse, mutect2
- AAGAB | c.281G>T p.S94I | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.341); called by muse, mutect2
- ABCA2 | c.7046A>C p.Y2349S (on ENST00000614293; = p.Y2319S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/426 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2
- AC013489.1 | c.1520G>A p.G507D | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ADAM33 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2
- ADGB | c.4035G>T p.Q1345H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- ANO5 | c.2190G>T p.W730C | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- ANO6 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AP4E1 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ARSF | c.1089T>A p.N363K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2
- B3GAT2 | c.498G>T p.W166C | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BATF | c.23G>T p.S8I | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2
- BBS7 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.092); called by muse, mutect2
- BHMT | c.478T>A p.Y160N | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BOD1L2 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- BRPF3 | c.845C>G p.T282S | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BRPF3 | c.3308G>T p.G1103V | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- C10orf71 | c.1329C>G p.I443M | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAPZA1 | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- CBLL2 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- CCDC15 | c.1273G>T p.D425Y | Missense Mutation (SNP) | VAF 27/361 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); called by muse, mutect2
- CD22 | c.1408C>A p.L470M | Missense Mutation (SNP) | VAF 96/618 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.315); called by muse, varscan2
- CDC20B | c.1006C>A p.R336S | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CELSR3 | c.7465G>C p.A2489P | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- CFAP46 | c.7191C>A p.G2397= | Splice Region (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- CFAP54 | c.6203C>A p.S2068Y | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- CFAP74 | c.3062T>C p.L1021P | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHERP | c.669C>G p.H223Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CITED4 | c.158C>A p.P53Q | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); called by muse, mutect2
- CLEC1A | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- CLNK | c.344G>T p.R115M | Missense Mutation (SNP) | VAF 24/353 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2
- CNTNAP4 | c.3784G>T p.V1262F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.221); called by muse, mutect2
- COL12A1 | c.2544T>G p.Y848* | Nonsense Mutation (SNP) | VAF 24/320 reads (8%) | called by muse, mutect2
- COL3A1 | c.1573G>A p.G525S | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL4A2 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2
- COPS5 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.033); called by muse, mutect2
- CORO2B | c.1151G>T p.W384L | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRACD | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- CSMD2 | c.9884G>T p.R3295I | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2
- CSTF2 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- CTTN | c.625A>T p.S209C | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2
- DCAF1 | c.405G>T p.W135C | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DCAF1 | c.404G>T p.W135L | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2
- DCSTAMP | c.1264G>T p.A422S | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2
- DDX10 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DGKI | c.2300G>T p.G767V | Missense Mutation (SNP) | VAF 17/265 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); called by muse, mutect2
- DGKI | c.2299G>T p.G767* | Nonsense Mutation (SNP) | VAF 18/265 reads (7%) | called by muse, mutect2
- DMRTB1 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 17/364 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.097); called by muse, mutect2
- DNAH12 | c.6762G>T p.L2254F (on ENST00000351747; = p.L2273F on NM_001366028.2) | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH12 | c.2584C>A p.Q862K (on ENST00000351747; = p.Q885K on NM_001366028.2) | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DNAH7 | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- DNTTIP2 | c.963G>C p.K321N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DUS1L | c.422C>G p.S141C | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2
- EFCAB12 | c.1112G>C p.C371S | Missense Mutation (SNP) | VAF 62/467 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- EFCAB9 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- EHBP1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM172A | c.971A>T p.H324L | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FAT3 | c.13216C>A p.P4406T | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2
- FCHO1 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2
- FCRL4 | c.806A>G p.N269S | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- FLNC | c.2550G>T p.Q850H | Missense Mutation (SNP) | VAF 33/520 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2
- FSCB | c.2407G>C p.G803R | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.299); called by muse, varscan2
- GLRB | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- GOLGB1 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by mutect2, varscan2
- GPHN | c.1940A>T p.Q647L (on ENST00000315266 / NM_001377519.1; = p.Q680L on NM_020806.5) | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- GPR158 | c.2498G>C p.S833T | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2
- GREB1 | c.1178A>T p.Y393F | Missense Mutation (SNP) | VAF 37/552 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2
- GRIA3 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 15/117 reads (13%) | called by muse, mutect2, varscan2
- GTF3C2 | c.1168T>A p.S390T | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.041); called by muse, mutect2
- GTF3C5 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2
- IGHG4 | c.305A>T p.Y102F | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- IGKV2-24 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 18/449 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- INHBC | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- KARS1 | c.373A>T p.T125S | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- KCNB2 | c.2666T>C p.L889S | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.344); called by muse, mutect2
- KCNH5 | c.1030T>A p.Y344N | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNMA1 | c.3338T>A p.L1113* (on ENST00000286628 / NM_001161352.2; = p.L1055* on NM_002247.4) | Nonsense Mutation (SNP) | VAF 14/398 reads (4%) | called by muse, mutect2
- LAMB4 | c.581C>A p.T194K | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- MAGEA1 | c.83T>A p.V28E | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- MASP1 | c.503G>T p.C168F | Missense Mutation (SNP) | VAF 75/517 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MATR3 | c.910A>T p.K304* | Nonsense Mutation (SNP) | VAF 14/249 reads (6%) | called by muse, mutect2
- MATR3 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.122); called by muse, mutect2
- MEFV | c.1058C>A p.P353H | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.818); called by muse, mutect2
- MEFV | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.477); called by muse, mutect2
- MEX3D | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 35/422 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2
- MGAM | c.4723G>T p.G1575W | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MLXIP | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- MS4A2 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MS4A8 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- MYH10 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MYH2 | c.4398T>A p.C1466* | Nonsense Mutation (SNP) | VAF 35/257 reads (14%) | called by muse, mutect2, varscan2
- MYH8 | c.3755G>T p.C1252F | Missense Mutation (SNP) | VAF 45/605 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2
- MYLK2 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- NAT14 | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NBR1 | c.100A>T p.M34L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- NECAP1 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- NPHP4 | c.3044G>T p.S1015I | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NPL | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- NPY5R | c.635C>G p.T212S | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.145); called by muse, mutect2
- NR3C2 | c.1358T>C p.M453T | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- OR10V1 | c.324G>T p.L108F | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.059); called by muse, mutect2
- OR2T2 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 26/778 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR4C12 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- OR4C6 | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.144); called by muse, mutect2
- OR4K2 | c.596T>A p.M199K | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- OR4X1 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- P2RY1 | c.903G>T p.R301S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PCDH11X | c.1806T>A p.N602K | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCDH7 | c.2294C>A p.T765K | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, mutect2
- PES1 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); called by muse, mutect2
- PKHD1 | c.3841G>T p.G1281C | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); called by muse, mutect2
- PLEKHD1 | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- PLEKHH1 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- POM121L2 | c.2365C>G p.P789A | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); called by muse, mutect2
- PPP4R3C | c.2147T>A p.M716K | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2
- PRAME | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2
- PRKCG | c.608A>T p.D203V | Missense Mutation (SNP) | VAF 86/589 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- RAB6A | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAD51AP2 | c.2584G>C p.D862H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.042); called by muse, mutect2
- RB1CC1 | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.062); called by muse, mutect2
- RELN | c.5071G>T p.G1691C | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- REXO1 | c.2820G>T p.K940N | Missense Mutation (SNP) | VAF 29/361 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2
- RIMBP2 | c.1501C>A p.P501T | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIT2 | c.602T>A p.L201Q | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2
- RPS6KA6 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2
- RPTN | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2
- RSKR | c.955A>T p.S319C | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RTRAF | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); called by muse, mutect2
- RYR3 | c.4792C>A p.L1598I | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); called by muse, mutect2
- SDK1 | c.4337C>G p.S1446C | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SEMA6B | c.920C>A p.A307D | Missense Mutation (SNP) | VAF 38/526 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SEPTIN14 | c.288T>A p.Y96* | Nonsense Mutation (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- SHANK3 | c.5089A>G p.K1697E | Missense Mutation (SNP) | VAF 36/835 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2
- SIX3 | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 70/762 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.013); called by muse, mutect2
- SLC11A1 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC11A1 | c.954G>T p.A318= | Splice Region (SNP) | VAF 9/55 reads (16%) | called by mutect2, varscan2
- SLC17A4 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2
- SLC22A8 | c.1313C>A p.P438H | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLITRK3 | c.1449C>A p.H483Q | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SPATS1 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.726); called by muse, mutect2
- SPOCK3 | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPOCK3 | c.795C>A p.D265E | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SSRP1 | c.1989A>T p.K663N | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- TAS2R16 | c.174T>A p.C58* | Nonsense Mutation (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- TENM3 | c.7477A>T p.K2493* | Nonsense Mutation (SNP) | VAF 28/295 reads (9%) | called by muse, mutect2
- TGM6 | c.1261G>T p.G421W | Missense Mutation (SNP) | VAF 32/598 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TIAM1 | c.1812C>A p.I604= | Splice Region (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- TMEM196 | c.4T>A p.C2S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- TMX3 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TNS1 | c.1732A>T p.M578L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV12-1 | c.186G>T p.R62S | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2
- TRBV29-1 | c.251G>C p.S84T | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- UGT2B4 | c.539T>C p.I180T | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.102); called by muse, mutect2
- UNC79 | c.5869C>T p.P1957S (on ENST00000393151 / NM_001346218.2; = p.P1780S on NM_020818.5) | Missense Mutation (SNP) | VAF 27/350 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- UNC79 | c.5870C>T p.P1957L (on ENST00000393151 / NM_001346218.2; = p.P1780L on NM_020818.5) | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2
- UNC93B1 | c.410G>T p.W137L | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- VIRMA | c.4828G>C p.E1610Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- VN1R4 | c.896G>C p.W299S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by mutect2, varscan2
- VN1R5 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- VPS13B | c.8947A>G p.I2983V | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2
- WDFY3 | c.4519-2A>G p.X1507_splice | Splice Site (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- WDR33 | c.1888G>T p.G630* | Nonsense Mutation (SNP) | VAF 18/189 reads (10%) | called by muse, mutect2
- ZBTB33 | c.1936C>G p.Q646E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZFYVE28 | c.2164G>T p.G722C | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2
- ZNF320 | c.932A>T p.K311M | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ZNF335 | c.1134G>T p.Q378H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.172); called by muse, mutect2
- ZNF366 | c.1807G>T p.V603L | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2
- ZNF496 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 33/574 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF525 | c.692G>T p.R231M | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ZNF736 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- ZNF91 | c.2789G>T p.R930M | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2
- ZNF91 | c.2787G>T p.K929N | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- A2ML1 | c.2037C>G p.G679= | Silent (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
- ATF7IP | c.555C>G p.S185= | Silent (SNP) | VAF 74/467 reads (16%) | called by muse, mutect2, varscan2
- CBARP | c.987C>G p.V329= (on ENST00000382477; = p.V309= on NM_152769.3) | Silent (SNP) | VAF 31/344 reads (9%) | called by muse, mutect2
- CCN5 | c.642C>A p.T214= | Silent (SNP) | VAF 20/314 reads (6%) | called by muse, mutect2
- CCNL2 | c.1143G>T p.R381= | Silent (SNP) | VAF 18/317 reads (6%) | called by muse, mutect2
- CD46 | c.90C>T p.S30= | Silent (SNP) | VAF 46/572 reads (8%) | catalogued as rs1397385235; called by muse, mutect2
- CNTNAP2 | c.2067C>T p.F689= | Silent (SNP) | VAF 23/349 reads (7%) | catalogued as COSV62265226; called by muse, mutect2
- CWC22 | c.2724A>G p.K908= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs769782797; called by mutect2, varscan2
- DCLK3 | c.1242C>T p.I414= | Silent (SNP) | VAF 18/302 reads (6%) | catalogued as rs770926877, COSV101374002; called by muse, mutect2
- ELFN1 | c.1770C>A p.P590= | Silent (SNP) | VAF 32/270 reads (12%) | called by muse, mutect2, varscan2
- EVX1 | c.156C>T p.A52= | Silent (SNP) | VAF 38/391 reads (10%) | catalogued as rs1394355234; called by muse, mutect2
- EXPH5 | c.5115C>T p.N1705= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as rs1352253610, COSV56207420; called by muse, mutect2, varscan2
- FES | c.867A>G p.E289= | Silent (SNP) | VAF 53/289 reads (18%) | called by muse, mutect2, varscan2
- FREM3 | c.5898C>A p.V1966= | Silent (SNP) | VAF 40/440 reads (9%) | called by muse, mutect2
- FTO | c.642C>T p.Y214= | Silent (SNP) | VAF 40/443 reads (9%) | called by muse, mutect2
- GPR101 | c.1347C>A p.I449= | Silent (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- HAND1 | c.312G>C p.R104= | Silent (SNP) | VAF 36/764 reads (5%) | called by muse, mutect2
- HECW1 | c.1659C>T p.P553= | Silent (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- IGKV4-1 | c.243A>G p.E81= | Silent (SNP) | VAF 102/581 reads (18%) | catalogued as rs369161039; called by muse, mutect2, varscan2
- IRX4 | c.1452C>A p.P484= | Silent (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- KCNA1 | c.1218C>T p.V406= | Silent (SNP) | VAF 40/270 reads (15%) | catalogued as COSV101230190; called by muse, mutect2, varscan2
- KCNJ12 | c.16C>A p.R6= | Silent (SNP) | VAF 24/478 reads (5%) | called by muse, mutect2
- KIF26A | c.4824C>T p.A1608= | Silent (SNP) | VAF 21/200 reads (11%) | catalogued as rs929279402; called by muse, mutect2, varscan2
- KIF6 | c.864A>T p.S288= | Silent (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- KRTAP4-7 | c.379C>A p.R127= | Silent (SNP) | VAF 41/327 reads (13%) | catalogued as rs192165506; called by mutect2, varscan2
- LHFPL3 | c.558C>A p.A186= | Silent (SNP) | VAF 20/376 reads (5%) | called by muse, mutect2
- LRRC4B | c.555G>A p.R185= | Silent (SNP) | VAF 49/325 reads (15%) | catalogued as rs761524693; called by muse, mutect2, varscan2
- MGAM | c.4806G>A p.V1602= | Silent (SNP) | VAF 22/419 reads (5%) | called by muse, mutect2
- MICAL3 | c.2709T>A p.A903= | Silent (SNP) | VAF 26/452 reads (6%) | called by muse, mutect2
- MMP16 | c.558T>A p.I186= | Silent (SNP) | VAF 22/296 reads (7%) | called by muse, mutect2
- MSRB3 | c.30C>A p.P10= | Silent (SNP) | VAF 44/308 reads (14%) | called by muse, mutect2, varscan2
- MUC19 | c.294G>C p.G98= | Silent (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- NCKAP5 | c.4176C>A p.T1392= | Silent (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- OR3A1 | c.330C>T p.F110= | Silent (SNP) | VAF 22/195 reads (11%) | catalogued as rs375681384; called by muse, mutect2, varscan2
- OR5W2 | c.630C>A p.T210= | Silent (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- PCDHB13 | c.720C>G p.A240= | Silent (SNP) | VAF 63/1043 reads (6%) | called by muse, mutect2
- PCDHB15 | c.1317G>A p.V439= | Silent (SNP) | VAF 48/394 reads (12%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.1683G>A p.E561= | Silent (SNP) | VAF 52/515 reads (10%) | called by muse, mutect2, varscan2
- PHLDB3 | c.927G>A p.E309= | Silent (SNP) | VAF 50/295 reads (17%) | called by muse, mutect2, varscan2
- PIK3CB | c.2550C>T p.L850= | Silent (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- PKD2 | c.2328G>A p.Q776= | Silent (SNP) | VAF 23/315 reads (7%) | called by muse, mutect2
- PLXNA4 | c.3600C>A p.L1200= | Silent (SNP) | VAF 27/328 reads (8%) | called by muse, mutect2
- PNPLA3 | c.1059T>C p.Y353= | Silent (SNP) | VAF 18/264 reads (7%) | catalogued as rs1182686479; called by muse, mutect2
- POM121L12 | c.585G>T p.P195= | Silent (SNP) | VAF 20/345 reads (6%) | catalogued as COSV68692555; called by muse, mutect2
- PSD | c.129A>G p.T43= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- S1PR4 | c.732C>T p.R244= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- SACS | c.7977A>T p.T2659= | Silent (SNP) | VAF 5/43 reads (12%) | called by mutect2, varscan2
- SDF2 | c.90G>A p.V30= | Silent (SNP) | VAF 14/236 reads (6%) | called by muse, mutect2
- SIRPB1 | c.1194C>G p.A398= | Silent (SNP) | VAF 21/121 reads (17%) | called by muse, mutect2, varscan2
- SLC35G5 | c.54G>T p.P18= | Silent (SNP) | VAF 12/125 reads (10%) | called by muse, mutect2
- TMEM151A | c.18T>C p.A6= | Silent (SNP) | VAF 20/300 reads (7%) | catalogued as rs1262517025; called by muse, mutect2
- TNKS | c.3930C>T p.I1310= | Silent (SNP) | VAF 24/280 reads (9%) | called by muse, mutect2
- TNN | c.918G>A p.Q306= | Silent (SNP) | VAF 46/616 reads (7%) | catalogued as COSV99078406; called by muse, mutect2
- TNNI3K | c.2094G>T p.L698= | Silent (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- TRIM42 | c.933C>A p.T311= | Silent (SNP) | VAF 66/491 reads (13%) | catalogued as COSV53887437; called by muse, mutect2, varscan2
- TSPAN33 | c.402T>C p.I134= | Silent (SNP) | VAF 26/361 reads (7%) | called by muse, mutect2
- TTN | c.77520C>A p.I25840= (on ENST00000591111; = p.I18416= on NM_003319.4) | Silent (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- TTN | c.516G>C p.G172= | Silent (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- TYK2 | c.864G>T p.G288= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV53388970; called by muse, mutect2
- AC006305.1 | n.988C>A | RNA (SNP) | VAF 13/264 reads (5%) | called by muse, mutect2
- AC006372.4 | n.348C>T | RNA (SNP) | VAF 14/372 reads (4%) | called by muse, mutect2
- AL033384.1 | n.270C>A | RNA (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2
- APTX | c.*145A>G | 3'UTR (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- ATP13A1 | c.396+1196G>C | Intron (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- BTNL10 | n.314C>A | RNA (SNP) | VAF 14/314 reads (4%) | called by muse, mutect2
- CACNA1B | c.530+9510A>T | Intron (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- CTAGE13P | chr6:168293871 C>A | 5'Flank (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- CTBP1 | c.41-3104G>T | Intron (SNP) | VAF 28/275 reads (10%) | called by muse, mutect2
- CTBP1 | c.41-3105G>T | Intron (SNP) | VAF 26/276 reads (9%) | called by muse, mutect2
- ELFN1 | c.-456+5588G>T | Intron (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- FAM183BP | n.353C>A | RNA (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- FLJ40288 | n.795C>A | RNA (SNP) | VAF 21/305 reads (7%) | called by muse, mutect2
- GCLM | c.192+72C>T | Intron (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- GDF3 | c.*13G>T | 3'UTR (SNP) | VAF 43/224 reads (19%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1534G>T | RNA (SNP) | VAF 35/305 reads (11%) | catalogued as rs760970633; called by muse, mutect2, varscan2
- KCNAB2 | c.119+9835C>A | Intron (SNP) | VAF 23/308 reads (7%) | called by muse, mutect2
- LINC00452 | n.743C>A | RNA (SNP) | VAF 13/242 reads (5%) | called by muse, mutect2
- LRRC37A6P | n.2492C>A | RNA (SNP) | VAF 18/546 reads (3%) | called by muse, mutect2
- MARCHF1 | c.242+327T>G | Intron (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- MARCHF1 | c.-322-85717C>G | Intron (SNP) | VAF 35/500 reads (7%) | called by muse, mutect2
- MARCHF5 | c.-56G>T | 5'UTR (SNP) | VAF 28/427 reads (7%) | called by muse, mutect2
- MIR6511A3 | chr16:16372514 C>A | 3'Flank (SNP) | VAF 18/90 reads (20%) | called by mutect2, varscan2
- MLIP | c.613-11228G>T | Intron (SNP) | VAF 19/351 reads (5%) | called by muse, mutect2
- MSLNL | c.503+57G>T | Intron (SNP) | VAF 24/319 reads (8%) | called by muse, mutect2
- MUC19 | chr12:40544865 A>G | 3'Flank (SNP) | VAF 12/218 reads (6%) | catalogued as rs920680372; called by muse, mutect2
- NAA60 | c.*234del | 3'UTR (DEL) | VAF 13/117 reads (11%) | called by mutect2, pindel, varscan2
- NBR2 | n.470T>A | RNA (SNP) | VAF 28/538 reads (5%) | called by muse, mutect2
- NLN | c.42-17603C>A | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- NOS1 | c.-1C>A | 5'UTR (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- NOX4 | c.-6G>T | 5'UTR (SNP) | VAF 19/212 reads (9%) | called by muse, mutect2
- OVCH1-AS1 | n.524A>T | RNA (SNP) | VAF 16/376 reads (4%) | called by muse, mutect2
- PCDHB6 | chr5:141156717 C>A | 3'Flank (SNP) | VAF 30/232 reads (13%) | called by muse, mutect2, varscan2
- PHB2 | c.867-35_867-34del | Intron (DEL) | VAF 34/332 reads (10%) | catalogued as rs782405998; called by pindel, varscan2
- PNCK | chrX:153674140 G>C | 5'Flank (SNP) | VAF 20/134 reads (15%) | catalogued as COSV100562289; called by muse, mutect2, varscan2
- PPP2R1A | c.78+62del | Intron (DEL) | VAF 22/126 reads (17%) | called by mutect2, pindel, varscan2
- SEC13 | c.-42G>C | 5'UTR (SNP) | VAF 7/153 reads (5%) | catalogued as rs1299675725; called by muse, mutect2
- SHBG | c.112-49G>A | Intron (SNP) | VAF 35/328 reads (11%) | catalogued as rs776432399; called by muse, mutect2, varscan2
- SOHLH1 | c.-25G>T | 5'UTR (SNP) | VAF 30/382 reads (8%) | called by muse, mutect2
- SORL1 | c.4214-143G>C | Intron (SNP) | VAF 15/234 reads (6%) | catalogued as COSV52752045; called by muse, mutect2
- SSPOP | n.7617G>C | RNA (SNP) | VAF 18/278 reads (6%) | called by muse, mutect2
- TENM2 | c.503-120809G>A | Intron (SNP) | VAF 21/116 reads (18%) | called by muse, mutect2, varscan2
- TPP1 | c.886+46G>T | Intron (SNP) | VAF 25/280 reads (9%) | called by muse, mutect2
- TRAPPC2L | c.374+15C>T | Intron (SNP) | VAF 18/194 reads (9%) | catalogued as rs1237741167; called by muse, mutect2
- USP39 | chr2:85612334 G>T | 5'Flank (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- XIST | n.11107G>A | RNA (SNP) | VAF 28/157 reads (18%) | catalogued as rs1206107405; called by muse, mutect2, varscan2
